TCGA case TCGA-DX-AB3A — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cabd63ee-d833-47b0-9a0b-8a046d260af1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 80 years; Vital status: Dead; Days to death: 978 days (2.7 years).

Diagnoses (4)
1. Dedifferentiated liposarcoma (the primary disease): ICD-O-3 morphology code: 8858/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 80.0 years (29,230 days); Year of diagnosis: 2009; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Lung, NOS; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis present: No; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 1.2.
2. Liposarcoma, well differentiated: ICD-O-3 morphology code: 8851/3; Tissue or organ of origin: Pelvis, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 72.5 years (26,467 days); Days to diagnosis: -2,763 days (-7.6 years).
3. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma). Age at diagnosis: 81.5 years (29,763 days); Days to diagnosis: 533 days (1.5 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 2; Tumor length measurement: 4; Tumor width measurement: 2.9.
4. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma), site: Lung, NOS. Age at diagnosis: 82.2 years (30,015 days); Days to diagnosis: 785 days (2.1 years); Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Radiologic; Tumor burden: 6.7.

Follow-up (4 entries)
- Day 533 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 533 days (1.5 years).
- Day 785 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 785 days (2.1 years); Discontiguous lesion count: 3.
- Day 785 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 785 days (2.1 years).
- Days to follow up: 978 days (2.7 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-AB3A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,080 mg.
  Slide TCGA-DX-AB3A-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-AB3A-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-AB3A-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.
- Primary pathology: Margin status: Negative; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: Yes; Metastasis site: Lung.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Groin; Other malignancy histological type: Well differentiated liposarcoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Excision groin.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 978 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 978 days; disease-free interval: event (new tumor event after initially disease-free), 533 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 533 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-AB3A-01A-11D-A416-01): tumor purity 0.87, ploidy 2.07, whole-genome doublings 0.
